Somatic mutation profile of tumor specimen TCGA-CH-5771-01A (aliquot TCGA-CH-5771-01A-21D-1576-08) from TCGA case TCGA-CH-5771, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.2 years (23,101 days).
Specimen TCGA-CH-5771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc1cd411-3dde-44d2-afbc-c118681460c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5771-11A (Solid Tissue Normal), aliquot TCGA-CH-5771-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0573b3d1-4aae-4a31-9206-cf80ec67bc5e

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1393086626, COSV52154632; called by muse, mutect2, varscan2
- BIN2 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 51/421 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs769557937, COSV57205697; called by muse, mutect2, varscan2
- CDKN2AIPNL | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV67655189; called by muse, mutect2
- CDR1 | c.156G>T p.L52F | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV65164704; called by muse, mutect2, varscan2
- CSMD2 | c.4529C>T p.P1510L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53953989, COSV99587451; called by muse, mutect2
- DMD | c.7945C>T p.R2649W | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1015097529, COSV58945714; called by muse, mutect2, varscan2
- ELAPOR2 | c.1172A>G p.E391G (on ENST00000450689 / NM_001142749.3; = p.E224G on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.283); catalogued as COSV51890952; called by muse, mutect2
- KIAA0319L | c.2332A>G p.T778A | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57849823; called by muse, mutect2, varscan2
- MARK4 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1181867140, COSV53468076; called by muse, mutect2, varscan2
- MET | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV59267609, COSV59270429; called by muse, mutect2
- MSC | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs1410724629, COSV100335655, COSV57697415; called by muse, mutect2
- PDGFRA | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs750809787, COSV57270086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEE | c.2022G>C p.K674N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.097); catalogued as COSV100388087, COSV58230264; called by mutect2, varscan2
- RNF26 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60991335; called by muse, mutect2, varscan2
- RP1 | c.4269T>A p.C1423* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | catalogued as COSV55124876; called by muse, mutect2, varscan2
- SCN7A | c.4751G>T p.R1584I | Missense Mutation (SNP) | VAF 56/445 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101313256, COSV69274213; called by muse, mutect2, varscan2
- SF3A3 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.089); catalogued as COSV65956707; called by muse, mutect2, varscan2
- SIGLECL1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57064430; called by muse, mutect2, varscan2
- SLC13A5 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV53424815; called by muse, mutect2, varscan2
- ZFYVE9 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV55098779; called by muse, mutect2
- NEUROD2 | c.545_553del p.R182_D184del | In Frame Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- SHCBP1L | c.401_402del p.C134* | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- MRPL28 | c.513G>A p.R171= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1471689443, COSV51742090; called by mutect2, varscan2
- NPEPL1 | c.1443C>T p.A481= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV61940426; called by muse, mutect2, varscan2
- SBNO1 | c.78T>C p.I26= | Silent (SNP) | VAF 18/446 reads (4%) | catalogued as COSV57345139; called by muse, mutect2
- SV2C | c.216C>T p.D72= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs760204358, COSV59216333; called by muse, mutect2, varscan2
